Somatic mutation profile of tumor specimen MP2PRT-PAPKUS-TMP1-A (aliquot MP2PRT-PAPKUS-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPKUS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,302 days).
Specimen MP2PRT-PAPKUS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a32330f-0cd7-4a44-83de-0e831f86f270.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPKUS-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPKUS-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec74b72b-d108-47ff-8c7a-b628aac2e734

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 13, Silent 8.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL592490.1 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV69425699; called by muse, mutect2
- CD8A | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1427820128, COSV52156884; called by muse, mutect2
- GRAMD2A | c.653C>A p.S218Y | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1264394326; called by muse, mutect2
- ISYNA1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs11552754; called by muse, mutect2
- MUC5B | c.10136C>G p.S3379C | Missense Mutation (SNP) | VAF 48/552 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as rs1312270238, COSV71590145; called by muse, varscan2
- NEDD9 | c.2135A>G p.Y712C | Missense Mutation (SNP) | VAF 109/297 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.905); catalogued as rs758864980, COSV101060780; called by muse, mutect2, varscan2
- NUCB1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); catalogued as COSV54389081; called by muse, mutect2
- VPS37B | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs1293176526; called by muse, mutect2, varscan2
- ASPH | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 9/236 reads (4%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.006); called by muse, mutect2
- BIVM-ERCC5 | c.1561T>C p.F521L | Missense Mutation (SNP) | VAF 49/313 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCIN | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 92/239 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- FGFRL1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); called by muse, mutect2
- GSTM2 | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2
- ATXN1 | c.2301G>A p.A767= | Silent (SNP) | VAF 99/135 reads (73%) | catalogued as COSV55228783; called by muse, mutect2, varscan2
- CLTCL1 | c.3037C>T p.L1013= | Silent (SNP) | VAF 14/251 reads (6%) | called by muse, mutect2
- FAM189A2 | c.210C>G p.L70= | Silent (SNP) | VAF 14/333 reads (4%) | called by muse, mutect2
- FGFR2 | c.1695G>A p.E565= | Silent (SNP) | VAF 105/256 reads (41%) | called by muse, mutect2, varscan2
- FLNC | c.480G>A p.T160= | Silent (SNP) | VAF 34/198 reads (17%) | catalogued as rs369534561; called by mutect2, varscan2
- MTSS2 | c.516C>T p.N172= | Silent (SNP) | VAF 147/339 reads (43%) | catalogued as rs201007320, COSV58698615; called by muse, mutect2, varscan2
- PPFIA2 | c.2478G>A p.K826= | Silent (SNP) | VAF 22/299 reads (7%) | called by muse, mutect2
- TRIM39 | c.906G>A p.V302= | Silent (SNP) | VAF 20/273 reads (7%) | called by muse, mutect2
